Gene-level copy-number profile of tumor specimen TCGA-B6-A0I6-01A from TCGA case TCGA-B6-A0I6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 49.3 years (18,014 days).
Specimen TCGA-B6-A0I6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ba92130c-fd4f-492f-b4c8-8420a9d017f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0I6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS (2 files).
https://portal.gdc.cancer.gov/files/25ff10a6-a888-470b-8597-55720286a836

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 22,696; copy number 2: 33,400; copy number 3: 3,071; copy number 4: 574; copy number 5: 11; copy number 6: 20; copy number 8: 16; copy number 9: 1; copy number 10: 2; copy number 12: 6.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:185,738,804–185,833,290, 1 gene (within-gene range 0–1): FSIP2.
- chr4:91,319,034–91,605,292, 2 genes: AC074124.1, AC110774.1.
- chr6:81,724,722–81,736,353, 1 gene (within-gene range 0–1): AL078599.2.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr9:13,738,537–13,744,191, 1 gene: AL158157.1.
- chr11:29,594,326–29,631,515, 1 gene (within-gene range 0–2): LINC02546.
- chr11:112,977,353–112,977,420, 1 gene: RNU7-187P.
- chr12:91,050,491–91,058,024, 1 gene: KERA.
- chr14:63,371,364–63,641,861, 8 genes (within-gene range 0–1): PPP2R5E, AL132992.1, AL136038.3, AL136038.1, GCATP1, WDR89, AL136038.2, HSPE1P2.
- chr21:35,136,638–35,139,222, 1 gene: AF015262.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 56 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:13,386,130–13,836,571, 2 genes, copy number 10 (within-gene range 0–12): AL583785.1, LINC01235.
- chr9:13,927,971–15,362,134, 26 genes, copy number 6–12: LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33.
- chr18:60,628,963–60,902,726, 1 gene, copy number 8 (within-gene range 1–9): AC113137.1.
- chr18:60,794,613–62,980,433, 27 genes, copy number 5–9: HMGN1P31, CDH20, RNU6-116P, RPL30P14, AC090409.2, AC090409.1, AC105094.2, AC105094.1, LINC01544, RNF152, PIGN, RPIAP1, RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P.

Autosomal genes at a single copy (total copy number 1): 21,776. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
